Surgical pathology report (de-identified scan), TCGA case TCGA-QQ-A8VH, project TCGA-SARC (Sarcoma), tissue source site Roswell Park, specimen TCGA-QQ-A8VH-01A (Primary Tumor).

[page 1 of 3]
Date of Surgery:

SPECIMEN(S):

- A. PARASPINAL SOFT TISSUE
- B. EPIDURAL SCAR
- C. SPINAL CANAL MASS
- D. THORACIC SPINAL NERVE ROOT
- E. PARASPINAL RETROPLEURAL MASS T6
- F. NEURAL FORAMINAL TISSUE
- G. NEURAL FORAMINAL TISSUE T6
- H. DORSAL FORAMEN TISSUE
- I. POSTERIOR PARAVERTEBRAL SOFT TISSUE MARGIN

ICD-O-3
Tumor, peripheral nerve sheath
malignant 9540/3
Site ^{site} Retroperitoneum C48.0
path Soft Tissue NOS C49.9
W 1/21/14

CLINICAL HISTORY:

None provided.

PRE-OPERATIVE DIAGNOSIS:

Neurofibromatosis with intraspinal tumor

INTRAOPERATIVE CONSULTATION:

FSD: Thoracic spinal nerve root- Negative for tumor. Diagnosis called to Dr. at by Dr. .
FSF, Neural forminal tissue, biopsy: Positive for tumor
FSH, Dorsal foramen tissue, biopsy: Negative for tumor
FSI, Posterior paravertebral soft tissue margin: Negative for tumor
Diagnoses called at (F) and (H, I) by Dr.

GROSS DESCRIPTION:

A. PARASPINAL SOFT TISSUE

Received in formalin labeled with the patient's identification and designated "paraspinal soft tissue" is a fragment of soft white smooth surface tissue measuring 1.5 x 0.6 x 0.2 cm. Entirely submitted, A1.

B. EPIDURAL SCAR

Received in formalin labeled with the patient's identification and designated "epidural scar" are two fragments of red white firm tissue measuring 2.2 x 2.4 x 1.3 cm. Representatively submitted, B1.

C. SPINAL CANAL MASS

Received in formalin labeled with the patient's identification and designated "spinal canal mass" are multiple fragments of tan-white soft tissue measuring 2 x 1.5 x 0.3 cm in aggregate. Entirely submitted, C1.

D. THORACIC SPINAL NERVE ROOT

Received fresh for frozen section is a tan pink soft tissue fragment 1 x 0.9 x 0.7cm. Toto FSD.

E. PARASPINAL RETROPLEURAL MASS T6

Received fresh labeled with the patient's identification and designated "paraspinal retropleural mass T6" a portion of resected red-tan soft tissue measuring 3.7 x 3.3 x 2.2 cm. The surface inked black. Sectioning shows an encapsulated white soft mass measuring 3.5 x 3.2 x 2 cm,

[page 2 of 3]
Date of Surgery:

pushing against the external surface. A gross photograph is taken. A portion of the specimen is submitted for tissue procurement, the remainder entirely submitted, E1-E6.

F. NEURAL FORMINAL TISSUE

Received fresh labeled with the patient's identification and designated "neural forminal tissue" are multiple fragments of brown-red soft tissue measuring 1.2 x 1.1 x 0.6-cm in aggregate.

Entirely submitted for frozen section, FSF.

G. NEURAL FORMINAL TISSUE AT T6

Received in formalin labeled with the patient's identification and designated "neural forminal tissue T6" are multiple fragments of brown-tan soft tissue measuring 0.8 x 0.4 x 0.1 cm in aggregate. Entirely submitted, G1.

H. DORSAL FORAMEN TISSUE

Received fresh labeled with the patient's identification and designated "dorsal foramen tissue" is a fragment of tan soft tissue measuring 1.1 x 1 x 0.4 cm. Entirely submitted for frozen section, FSH.

I. POSTERIOR PARAVERTEBRAL SOFT TISSUE MARGIN

Received fresh labeled with the patient's identification and designated "posterior paravertebral soft tissue margin" is a fragment of tan soft tissue measuring 0.8 x 0.7 x 0.2 cm. Entirely submitted for frozen section, FSI.

DIAGNOSIS:

A. SOFT TISSUE, PARASPINAL, EXCISION:

- NEUROFIBROMA

B. SOFT TISSUE, EPIDURAL SCAR, EXCISION:

- SKELETAL MUSCLE WITH BIOPSY SITE CHANGES: EXTENSIVE FIBROSIS
AND FOCAL FOREIGN BODY GIANT CELL REACTION

C. SOFT TISSUE, SPINAL CANAL MASS, BIOPSY:

- PLEOMORPHIC MALIGNANT PERIPHERAL NERVE SHEATH TUMOR
INVOLVING CARTILAGE.

D. SOFT TISSUE, THORACIC SPINAL NERVE ROOT, BIOPSY:

- CAUTERIZED FIBROUS TISSUE.

E. SOFT TISSUE, PARASPINAL T6-RETROPLEURAL MASS, EXCISION:

- PLEOMORPHIC MALIGNANT PERIPHERAL NERVE SHEATH TUMOR
ARISING FROM, AND WITH SUBTOTAL EFFACEMENT OF, LARGE NERVE.
- INKED/CAUTERIZED MARGINS ARE FOCALLY INVOLVED.

F. SOFT TISSUE, NEURAL FORAMEN, EXCISION:

- MALIGNANT PERIPHERAL NERVE SHEATH TUMOR FOCALLY PRESENT.

G. SOFT TISSUE, NEURAL FORAMEN T6, EXCISION:

- MALIGNANT PERIPHERAL NERVE SHEATH TUMOR FOCALLY PRESENT.

H. SOFT TISSUE, DORSAL FORAMEN, EXCISION:

[page 3 of 3]
Date of Surgery:

- NEUROFIBROMA

I. SOFT TISSUE, POSTERIOR PARAVERTEBRAL MARGIN, EXCISION:

- BENIGN NEURAL TISSUE, FAVOR NEUROFIBROMA

Source: NCI Genomic Data Commons file eed6c09d-0feb-4ed4-bafc-b94f25b12358 (TCGA-QQ-A8VH.4BBD8F10-943C-401E-A996-BF385547D0DC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).